Somatic mutation profile of tumor specimen TCGA-B7-A5TN-01A (aliquot TCGA-B7-A5TN-01A-21D-A31L-08) from TCGA case TCGA-B7-A5TN, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.1 years (21,962 days).
Specimen TCGA-B7-A5TN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77ad8a30-f358-4ba4-b430-b6a5b461ce80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B7-A5TN-10A (Blood Derived Normal), aliquot TCGA-B7-A5TN-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/217114a1-a0d4-4b64-80fb-6ddf039b8d9e

The open-access MAF lists 92 somatic variants for this specimen: 63 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 27, Frame Shift Del 4, Frame Shift Ins 2, Nonsense Mutation 2, Intron 1, Splice Site 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.857A>G p.E286G | Missense Mutation (SNP) | VAF 28/46 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRL3 | c.2665T>G p.W889G (on ENST00000506720 / NM_001322402.2; = p.W821G on NM_015236.6) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184364877, COSV101547443; called by muse, mutect2
- AGPAT4 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV57243242; called by muse, mutect2, varscan2
- AHNAK2 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 111/429 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as rs777589450, COSV100319246; called by muse, mutect2, varscan2
- ARHGEF18 | c.2860G>A p.E954K (on ENST00000359920 / NM_001130955.2; = p.E850K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as rs993334421, COSV100150146; called by muse, mutect2, varscan2
- BBS12 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV100045138; called by muse, mutect2, varscan2
- CACNA1A | c.5651T>G p.L1884R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100803442; called by muse, mutect2, varscan2
- CCDC189 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs768683366, COSV100079582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGAS | c.1303T>C p.S435P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100943700; called by muse, mutect2, varscan2
- COL6A2 | c.3047G>A p.R1016H | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs376368468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNND1 | c.1563T>G p.I521M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV100650327; called by muse, mutect2, varscan2
- CYP2A7 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99394606; called by muse, mutect2, varscan2
- DDX3X | c.1463C>A p.S488* (on ENST00000399959; = p.S489* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 36/48 reads (75%) | catalogued as COSV101302537; called by muse, mutect2, varscan2
- DLGAP2 | c.2263G>T p.G755W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262675720, COSV101422952, COSV101423006; called by muse, mutect2, varscan2
- DMGDH | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99669637; called by muse, mutect2, varscan2
- DNAH17 | c.4714G>A p.E1572K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101103809; called by muse, mutect2, varscan2
- DSEL | c.2468T>G p.F823C | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV100026196; called by muse, mutect2, varscan2
- DSEL | c.2344T>A p.F782I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as COSV100026197; called by muse, mutect2, varscan2
- F2R | c.527G>C p.R176P | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058675, COSV100058731, COSV59928497; called by muse, mutect2, varscan2
- FAM186B | c.247dup p.I83Nfs*17 | Frame Shift Ins (INS) | VAF 22/93 reads (24%) | catalogued as rs767474109; called by mutect2, pindel, varscan2
- FBN2 | c.3217+1G>A p.X1073_splice | Splice Site (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99331392; called by muse, varscan2
- FLG | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 72/416 reads (17%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.928); catalogued as COSV100912402; called by muse, mutect2, varscan2
- GALP | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV100628043; called by muse, mutect2, varscan2
- GRHL3 | c.791G>A p.R264Q (on ENST00000350501 / NM_198174.3; = p.R269Q on NM_021180.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as rs184435420, COSV99359784; called by muse, mutect2, varscan2
- GRID2 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as rs757924739, COSV56192980; called by muse, mutect2, varscan2
- HTR2A | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101096910; called by muse, mutect2, varscan2
- IFT80 | c.1439C>G p.A480G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100425207; called by muse, mutect2
- ITGA8 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs368464139; called by muse, mutect2, varscan2
- KCNJ2 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54661859; called by muse, mutect2, varscan2
- KCNK1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.414); catalogued as COSV100786051; called by muse, mutect2, varscan2
- KNL1 | c.94A>T p.S32C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100707172; called by muse, mutect2, varscan2
- LAD1 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV100943839, COSV100943984; called by muse, mutect2, varscan2
- LRRC15 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs373653527; called by muse, mutect2, varscan2
- LRRC18 | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV99628673, COSV99631250; called by muse, mutect2, varscan2
- MCF2 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV100645271; called by muse, mutect2, varscan2
- MORC3 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV101247776; called by muse, mutect2, varscan2
- NPAP1 | c.984G>C p.R328S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100276366, COSV61505370; called by muse, mutect2, varscan2
- OR10G8 | c.70C>G p.P24A | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV101461862, COSV101461896; called by muse, mutect2
- OR1L4 | c.24C>A p.S8R | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV99413990; called by muse, mutect2, varscan2
- OR2T8 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100178558; called by muse, mutect2, varscan2
- PCCA | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1047690554, COSV100887083; called by muse, mutect2, varscan2
- PHKA2 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101177645; called by muse, mutect2, varscan2
- PIK3C3 | c.1259A>C p.K420T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100011698; called by muse, mutect2
- PSKH2 | c.573C>A p.Y191* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV99405449; called by muse, mutect2, varscan2
- RAG2 | c.1002C>A p.D334E | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as COSV100271555; called by muse, mutect2, varscan2
- REV3L | c.3371C>T p.S1124F | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100725758; called by muse, mutect2, varscan2
- RGS11 | c.743T>G p.L248R (on ENST00000397770 / NM_183337.3; = p.L227R on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749840792, COSV99396105; called by muse, mutect2, varscan2
- ROGDI | c.699G>C p.E233D | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); catalogued as COSV100434213; called by muse, mutect2, varscan2
- RYR2 | c.3215C>A p.A1072E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.628); catalogued as COSV100773308; called by muse, mutect2, varscan2
- SLC28A2 | c.886A>C p.M296L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV100754843; called by mutect2, varscan2
- SMTN | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100295044, COSV60778817; called by muse, mutect2, varscan2
- STAG1 | c.3692G>A p.R1231Q | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.234); catalogued as COSV99367285; called by muse, mutect2, varscan2
- SYNE1 | c.15629T>A p.V5210E (on ENST00000367255 / NM_182961.4; = p.V5139E on NM_033071.3) | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV99583665; called by muse, mutect2, varscan2
- TET2 | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs762289112, COSV54438611; called by muse, mutect2, varscan2
- TRIM68 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs972702760, COSV56168182; called by muse, mutect2, varscan2
- ZNF324 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1160229145, COSV99543543; called by mutect2, varscan2
- ADAMTS6 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- BPTF | c.7558_7559del p.Q2520Tfs*128 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by pindel, varscan2
- CAMK4 | c.253del p.I85Sfs*2 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- CTCFL | c.831_832del p.K277Nfs*5 | Frame Shift Del (DEL) | VAF 17/143 reads (12%) | called by mutect2, pindel, varscan2
- H4C11 | c.82dup p.Q28Pfs*84 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by mutect2, varscan2
- OR8D4 | c.57del p.E19Dfs*14 | Frame Shift Del (DEL) | VAF 36/84 reads (43%) | called by mutect2, pindel*, varscan2
- RUNX2 | c.1542_1544del p.D514del (on ENST00000371438; = p.D492del on NM_001015051.3) | In Frame Del (DEL) | VAF 24/132 reads (18%) | called by pindel, varscan2*
- ALPG | c.1341C>T p.D447= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs141708728; called by muse, mutect2, varscan2
- ARMC4 | c.984C>A p.G328= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99519158; called by muse, mutect2, varscan2
- ASXL3 | c.6627G>A p.L2209= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99327052; called by muse, mutect2, varscan2
- CDK13 | c.3642G>A p.A1214= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs201950690, COSV99476212; called by muse, mutect2, varscan2
- COL27A1 | c.1053G>A p.A351= | Silent (SNP) | VAF 66/127 reads (52%) | catalogued as rs1421440467, COSV100620667, COSV100621236; called by muse, mutect2, varscan2
- CSMD3 | c.3558C>A p.G1186= (on ENST00000297405 / NM_001363185.1; = p.G1082= on NM_052900.3) | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as rs1333759646, COSV52326145, COSV99851282; called by muse, mutect2, varscan2
- DOCK6 | c.3456C>T p.Y1152= | Silent (SNP) | VAF 60/111 reads (54%) | catalogued as rs761619087, COSV99626967; ClinVar: likely benign; called by muse, mutect2, varscan2
- DZIP1L | c.1686G>A p.L562= | Silent (SNP) | VAF 19/176 reads (11%) | catalogued as COSV100551811; called by muse, mutect2
- ELOA2 | c.1056G>A p.P352= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs748051105, COSV99798503; called by muse, mutect2, varscan2
- FNDC1 | c.5652C>T p.Y1884= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs752764857, COSV99797309; called by muse, mutect2, varscan2
- GDF9 | c.516C>T p.V172= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV99737588; called by muse, mutect2
- IGHG3 | c.573C>T p.C191= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as rs587607987; called by muse, mutect2, varscan2
- KLK13 | c.612C>T p.A204= | Silent (SNP) | VAF 99/205 reads (48%) | catalogued as rs781158309, COSV99335493; called by muse, mutect2, varscan2
- LRRC37A3 | c.174G>A p.E58= | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as COSV100141573; called by muse, mutect2
- MACF1 | c.5682G>A p.L1894= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV99247468; called by muse, mutect2, varscan2
- MMP2 | c.1731C>T p.N577= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as COSV99528383; called by muse, mutect2, varscan2
- NRXN1 | c.4110G>A p.P1370= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs762505334, COSV60499110; called by muse, mutect2, varscan2
- OLFML2A | c.987C>T p.S329= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs562240897, COSV99992960; called by muse, mutect2, varscan2
- PSG5 | c.489T>C p.D163= | Silent (SNP) | VAF 52/329 reads (16%) | catalogued as COSV100743254; called by muse, mutect2, varscan2
- PTPRM | c.3345C>T p.A1115= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs756680864, COSV59851842, COSV59854909; called by muse, mutect2, varscan2
- RRAGD | c.228G>A p.S76= | Silent (SNP) | VAF 24/586 reads (4%) | catalogued as rs560624829, COSV100784657; called by muse, mutect2
- SRCAP | c.1446C>T p.P482= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as rs147749391; ClinVar: likely benign; called by muse, mutect2, varscan2
- TCEAL5 | c.282C>A p.A94= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as rs764460948, COSV101013204; called by muse, mutect2, varscan2
- TMC7 | c.1431C>T p.C477= | Silent (SNP) | VAF 37/251 reads (15%) | catalogued as rs769927626, COSV58584709; called by muse, mutect2, varscan2
- TMEM108 | c.252G>A p.P84= | Silent (SNP) | VAF 28/222 reads (13%) | catalogued as rs1055718719, COSV100418431; called by muse, mutect2, varscan2
- UROC1 | c.1395C>T p.D465= | Silent (SNP) | VAF 37/236 reads (16%) | catalogued as rs371652976; called by muse, mutect2, varscan2
- ZFR2 | c.417C>A p.G139= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99508027; called by muse, mutect2, varscan2
- LARP7 | c.1142+672C>A | Intron (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100135375; called by muse, mutect2, varscan2
- RPL26P30 | n.615T>C | RNA (SNP) | VAF 22/288 reads (8%) | catalogued as rs1283656242; called by muse, mutect2
